Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7Q6, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7Q6-01B (Primary Tumor).

[page 1 of 4]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology (OrderID:)	Final Results
-------------------------------	---------------

Surgical Pathology	Final
--------------------	-------

CASE NUMBER:
DIAGNOSIS:

1. Kidney, left, tumor, partial nephrectomy: Renal cell carcinoma, chromophobe type; margins of resection are free of tumor (see note).
2. Kidney, left, medial inferior margin, partial nephrectomy: Kidney parenchyma with chronic interstitial nephritis.
3. Kidney, left, lateral inferior margin, partial nephrectomy: Kidney parenchyma with chronic interstitial nephritis.

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS C64.9
JW 9/24/13

NOTE: Refer to the table below for staging information.

KIDNEY: Nephrectomy, Partial

Procedure
Partial nephrectomy

Specimen Laterality
Left

Tumor Site
Not specified

Tumor Size
Greatest dimension: 6.0 cm

Tumor Focality
Unifocal

Macroscopic Extent of Tumor
Tumor limited to kidney

Histologic Type
Chromophobe renal cell carcinoma

Sarcomatoid Features
Not identified

Tumor Necrosis
Not identified

Paner Grade
Grade 2: Geographic nuclear crowding (cellular clustering characterized by high geographic nuclear/cytoplasmic density detectable at 10x objective and some nuclei in direct contact with each other when assessed at 40x objective) and the presence of nuclear pleomorphism (size variation of ≥ 3 -fold and distinct nuclear chromatin irregularities (unlike the smudged nuclear atypia of degenerate foci)

[page 2 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

Microscopic Tumor Extension
Tumor limited to kidney

Margins
Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion
Not identified

Pathologic Staging (pTNM)
Primary Tumor (pT)
pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)
pNX: Regional lymph nodes cannot be assessed

No nodes submitted or found

Distant Metastasis (pM)
Not applicable

Pathologic Findings in Nonneoplastic Kidney
Significant pathologic alterations
Other (specify): Chronic interstitial nephritis

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: year old male with 7 cm left renal mass.

Specimen Taken For Protocol: 01 - Yes.

Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: left renal mass.

Post-Operative Diagnosis: same.

Operative Findings: 7 cm left renal mass.

SPECIMENS SUBMITTED: 1. KIDNEY, LEFT, Tumor
2. SOFT TISSUE, NOS, Normal Parenchyma Medial Inferior Margin
3. SOFT TISSUE, NOS, Normal Parenchyma Lateral Inferior Margin

GROSS DESCRIPTION: Received fresh are 3 separate specimens labeled

[page 3 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

with the patient's name, medical record number, and further specified as follows:

1. "Left renal tumor long stitch lateral short stitch inferior" consisting of a partial nephrectomy specimen measuring 8.0 x 6.3 x 6.5 cm. There is an area on the posterior-inferior surface where the margin is disrupted during surgery. The surgeon asks that the tumor from the inferior short stitch be sampled separately as it is a different color from the rest of the tumor. The anterior surface of the specimen is inked in black and a single incision is made revealing a tan-red friable cut surface. Approximately 50% of tissue from this surface is procured for . Two needle cores are additionally procured for . The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was documented and performed by on at . Received in Surgical Pathology is a specimen matching the above description. The posterior surface of the specimen is inked in blue. The deep inferior margin is entirely submitted in cassette . The nodule abutting the inferior margin is a golden yellow color. A representative section of this nodule is submitted in cassette IB-1C. The dominant nodule appears predominantly necrotic. Scar-like fibrous septae are identified coursing through this nodule. The dominant nodule measures 6.0 cm in greatest dimension. A representative section of the dominant nodule with respect to the posterior margin is submitted in cassette . Additional representative sections of the main nodule are submitted in cassettes . An additional section of the inferior margin nodule with respect to that margin is submitted in cassette . Additional representative sections of the dominant nodule are submitted in cassette . J. The remaining tissue is returned to formalin.

2. "Normal parenchyma medial inferior margin". The specimen consists of a tan-brown soft tissue fragment consistent with renal parenchyma measuring 3.5 x 3.5 x 1.0 cm. The specimen is serially sectioned and representative sections are submitted in cassettes .D. The remaining tissue is returned to formalin.

3. "Normal parenchyma lateral inferior margin" consisting of a portion of tan-brown soft tissue consistent with renal parenchyma measuring 1.5 x 1.0 x 0.5 cm. It is entirely submitted in cassette .

Gross Description dictated by

Accessioned:

Final Report Signed Out:

<Resident Signature>

[page 4 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology [OrderID:	Final Results
-------------------------------------	----------------------

<Sign Out Dr. Signature>

Date Report Signed:

Source: NCI Genomic Data Commons file d219b462-7d55-4d52-98ff-62e361b78638 (TCGA-KM-A7Q6.39549126-83BF-48D6-BDE6-5CE2A48A2E5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).